Somatic mutation profile of tumor specimen 0DR6YC from CCDI case PBCFRM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.8 years (6,488 days).
Specimen 0DR6YC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5854e8d8-be30-4890-919f-43296865eb5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR6Y3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46255f52-77bd-429e-a399-357107a3f17f

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2, 5'UTR 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.6642+2T>C p.X2214_splice (on ENST00000358273 / NM_001042492.3; = p.X2193_splice on NM_000267.3) | Splice Site (SNP) | VAF 313/838 reads (37%) | catalogued as CS000883; called by muse, mutect2, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 44/1240 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 44/1668 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- SEPTIN7 | c.1049T>C p.M350T | Missense Mutation (SNP) | VAF 219/1696 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- ZNF578 | c.1744T>G p.S582A | Missense Mutation (SNP) | VAF 30/532 reads (6%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.006); called by muse, mutect2
- COPB2 | c.-48G>C | 5'UTR (SNP) | VAF 56/391 reads (14%) | catalogued as COSV100300362; called by muse, mutect2, varscan2
- FLNA | c.7024-100G>C | Intron (SNP) | VAF 17/174 reads (10%) | catalogued as COSV104420173; called by muse, mutect2, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 20/436 reads (5%) | called by muse, mutect2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 10/90 reads (11%) | called by muse, varscan2
